Somatic mutation profile of tumor specimen MP2PRT-PATTEN-TMP1-A (aliquot MP2PRT-PATTEN-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATTEN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (615 days).
Specimen MP2PRT-PATTEN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2ca2123-1ac7-487b-904e-94beb70bc759.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATTEN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATTEN-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/732c5605-e929-4b1e-b4e8-a958d2e4a3aa

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLDN8 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as rs893943148, COSV54525776; called by muse, mutect2
- KRT20 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 53/672 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764730297, COSV51426070; called by muse, mutect2
- MRE11 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773766504, COSV60575456, COSV60579526; ClinVar: uncertain significance; called by muse, mutect2
- MYO15A | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 47/494 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs746585333; called by muse, mutect2
- PRSS53 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 46/530 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs376906210; called by muse, mutect2
- RGS19 | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58659601; called by muse, mutect2
- SIM1 | c.2112G>T p.Q704H | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV53493689; called by muse, mutect2
- ZNF382 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 25/396 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); catalogued as rs752791248, COSV53087739; called by muse, mutect2
- ARHGAP6 | c.1774C>A p.Q592K | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- DPP4 | c.1161C>A p.F387L | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2
- BOD1L1 | c.78G>A p.P26= | Silent (SNP) | VAF 9/176 reads (5%) | catalogued as rs1223923940; called by muse, mutect2
- GPR149 | c.1158G>A p.A386= | Silent (SNP) | VAF 21/181 reads (12%) | catalogued as COSV67666559; called by muse, mutect2, varscan2
- IGHV1-45 | c.353A>C p.*118= | Silent (SNP) | VAF 16/130 reads (12%) | called by mutect2, varscan2
- LAMA4 | c.279C>T p.D93= | Silent (SNP) | VAF 26/367 reads (7%) | catalogued as rs397516726, COSV54570965; ClinVar: likely benign; called by muse, mutect2
- MED25 | c.1413C>T p.V471= | Silent (SNP) | VAF 36/414 reads (9%) | catalogued as rs1381584254; called by muse, mutect2
